Somatic mutation profile of tumor specimen TARGET-10-PARTID-09A (aliquot TARGET-10-PARTID-09A-01D) from TARGET case TARGET-10-PARTID, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.6 years (5,315 days).
Specimen TARGET-10-PARTID-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52ce0a0e-82e9-44f0-8b2d-d5feab7f719a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTID-10A (Blood Derived Normal), aliquot TARGET-10-PARTID-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c670a79-ab83-4ca2-aee7-10b47b0516f2

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 2, 3'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 50/62 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- DRP2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs140021383; called by muse, mutect2, varscan2
- DSCAML1 | c.3632G>A p.R1211Q (on ENST00000321322; = p.R1151Q on NM_020693.4) | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.856); catalogued as rs141024479; called by muse, mutect2, varscan2
- FAM169B | n.257G>A | Splice Region (SNP) | VAF 41/94 reads (44%) | catalogued as rs750736779; called by muse, mutect2
- HELZ2 | c.2879G>A p.R960H (on ENST00000467148 / NM_001037335.2; = p.R391H on NM_033405.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs776734458, COSV64410350; called by muse, mutect2, varscan2
- HTRA1 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369288715; called by muse, mutect2, varscan2
- MUC16 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs367716629; called by muse, mutect2, varscan2
- TKTL2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1368882327; called by muse, mutect2, varscan2
- ZNF600 | c.955T>A p.S319T | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1334808803, COSV100593034; called by muse, mutect2, varscan2
- BMP8A | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); called by mutect2, varscan2
- ELL2 | c.319T>A p.S107T | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SST | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EXOC5 | c.1224G>A p.E408= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- OR2G2 | c.36A>G p.L12= | Silent (SNP) | VAF 43/117 reads (37%) | called by muse, mutect2, varscan2
- EFTUD2 | c.1861-75C>G | Intron (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- GNL3 | c.870-76A>G | Intron (SNP) | VAF 125/301 reads (42%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*1915A>C | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- TEDC1 | chr14:105491083 C>T | 5'Flank (SNP) | VAF 39/101 reads (39%) | catalogued as rs782609819; called by muse, mutect2, varscan2
